Somatic mutation profile of tumor specimen TCGA-Z7-A8R5-01A (aliquot TCGA-Z7-A8R5-01A-42D-A41F-09) from TCGA case TCGA-Z7-A8R5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.0 years (22,280 days).
Specimen TCGA-Z7-A8R5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 361b0d52-7a8d-4997-b771-99e98b5f35b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z7-A8R5-10A (Blood Derived Normal), aliquot TCGA-Z7-A8R5-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d21047df-85b4-4c25-8ad8-f008c7ff4163

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 3'Flank 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.211del p.L71Sfs*12 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as COSV55734761; called by mutect2, pindel, varscan2
- DHX9 | c.3751G>A p.G1251S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100841348, COSV100841485; called by muse, mutect2, varscan2
- DYNC1I1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1423892270, COSV61471293; called by muse, mutect2, varscan2
- F13A1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776782223, COSV99342697; called by muse, mutect2, varscan2
- FUT5 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as COSV99398671; called by mutect2, varscan2
- KIF20B | c.1783T>A p.L595I | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99589819; called by muse, mutect2
- MYH9 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99338498; called by muse, mutect2
- PCDHGA6 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs780491756, COSV53946936; called by muse, mutect2, varscan2
- PCDHGB2 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as rs1174960250, COSV53984178; called by muse, mutect2, varscan2
- SLITRK3 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs546557733, COSV53847830; called by muse, mutect2, varscan2
- SLU7 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99775540; called by muse, varscan2
- SPDL1 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs750996171, COSV99517490; called by muse, mutect2, varscan2
- TMEM79 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs762068186, COSV99827848; called by muse, mutect2, varscan2
- RNF133 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPTLC1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- TBX3 | c.1099+1dup p.X367_splice (on ENST00000257566 / NM_016569.4; = p.X347_splice on NM_005996.4) | Splice Site (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- DNM1 | c.1722C>T p.D574= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1404706727, COSV100359778; called by muse, mutect2, varscan2
- GBA2 | c.558C>T p.I186= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1325832670, COSV100960169; called by muse, mutect2, varscan2
- GJA8 | c.366C>T p.G122= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs782125496; called by muse, mutect2, varscan2
- PCDHA6 | c.1920G>A p.A640= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs554678736, COSV100971389; called by muse, mutect2, varscan2
- ZC3H13 | c.2053C>A p.R685= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99667907; called by muse, mutect2
- EHMT1 | chr9:137838456 C>T | 3'Flank (SNP) | VAF 10/75 reads (13%) | catalogued as rs750100099; called by muse, mutect2, varscan2
- SNORD115-6 | n.76G>A | RNA (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
